Somatic mutation profile of tumor specimen TCGA-D1-A16D-01A (aliquot TCGA-D1-A16D-01A-11D-A12J-09) from TCGA case TCGA-D1-A16D, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G2; Age at diagnosis: 49.1 years (17,933 days).
Specimen TCGA-D1-A16D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e9f9f19-a31d-40cb-abb4-df50b05494a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16D-10A (Blood Derived Normal), aliquot TCGA-D1-A16D-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7de67541-0242-4b49-89cb-751552c24e79

The open-access MAF lists 43 somatic variants for this specimen: 36 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Nonsense Mutation 3, Splice Site 3, Translation Start Site 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 83/287 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 84/222 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 145/253 reads (57%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- RBM39 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 73/258 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV53614904; called by muse, mutect2, varscan2
- ABCA2 | c.2690C>T p.A897V (on ENST00000614293; = p.A867V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs867972406, COSV55804275; called by muse, mutect2, varscan2
- ADGRA3 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs144467569; called by muse, mutect2, varscan2
- ALK | c.1414+1G>A p.X472_splice | Splice Site (SNP) | VAF 28/92 reads (30%) | catalogued as rs777414641, COSV66557567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMBRA1 | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.978); catalogued as rs746745526, COSV54059490; called by muse, mutect2, varscan2
- APOBR | c.2554C>A p.Q852K (on ENST00000431282; = p.Q861K on NM_018690.4) | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.23); catalogued as COSV60492550; called by muse, mutect2, varscan2
- ARID1A | c.6139G>T p.E2047* | Nonsense Mutation (SNP) | VAF 125/387 reads (32%) | catalogued as COSV100251081, COSV61373194; called by muse, mutect2, varscan2
- BNC2 | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV66152892; called by mutect2, varscan2
- CD69 | c.387+2T>C p.X129_splice | Splice Site (SNP) | VAF 33/103 reads (32%) | catalogued as COSV57303335; called by muse, mutect2, varscan2
- CDC16 | c.1240C>G p.Q414E | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52960850; called by muse, mutect2, varscan2
- CDH10 | c.1440G>T p.L480F | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs77909063, COSV52590263; called by muse, mutect2, varscan2
- COL1A2 | c.3482G>A p.R1161H | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542912072, COSV51957205; called by muse, mutect2, varscan2
- COL5A1 | c.1034A>G p.D345G | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65672673; called by muse, mutect2, varscan2
- CREBBP | c.4311T>G p.I1437M | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52133987; called by muse, mutect2, varscan2
- DNAH9 | c.9103C>T p.R3035C | Missense Mutation (SNP) | VAF 63/299 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201172849; called by muse, mutect2, varscan2
- DZIP3 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs773750250, COSV100847575, COSV64313069; called by muse, mutect2, varscan2
- GPKOW | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV50244063; called by muse, mutect2, varscan2
- HUWE1 | c.3641C>T p.T1214M | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.429); catalogued as rs782621365, COSV53356843; called by muse, mutect2, varscan2
- KCNJ16 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1164479923, COSV52255729; called by muse, mutect2
- LMBR1L | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV57268558; called by muse, mutect2, varscan2
- MED24 | c.1445G>A p.S482N | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1344099212, COSV62420036; called by muse, mutect2, varscan2
- MYO16 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs750664162, COSV51807663; called by muse, mutect2, varscan2
- OR4K1 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 91/408 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV53461107, COSV53461444; called by muse, mutect2, varscan2
- PATZ1 | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV53230475; called by muse, mutect2, varscan2
- PCDHGA12 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as COSV52760288; called by muse, mutect2, varscan2
- PHF24 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs770459611, COSV54272877, COSV99646284; called by muse, mutect2, varscan2
- SCN3A | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 139/509 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs775711350, COSV51818036; called by muse, mutect2, varscan2
- TRGV4 | c.226G>C p.V76L | Missense Mutation (SNP) | VAF 77/338 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as rs375308633; called by muse, mutect2, varscan2
- UBASH3B | c.1310A>G p.K437R | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV52499061; called by muse, mutect2, varscan2
- CTCF | c.1072dup p.Y358Lfs*51 | Frame Shift Ins (INS) | VAF 48/238 reads (20%) | called by mutect2, pindel, varscan2
- FKBP3 | c.410del p.G137Efs*26 | Frame Shift Del (DEL) | VAF 91/372 reads (24%) | called by mutect2, pindel, varscan2
- GTF3C2 | c.2410-4_2419del p.X804_splice | Splice Site (DEL) | VAF 17/82 reads (21%) | called by pindel, varscan2*
- NBPF11 | c.575A>G p.Q192R | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ARHGAP31 | c.729G>A p.L243= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV51796573; called by muse, mutect2, varscan2
- CACNA1C | c.168C>T p.I56= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs763760402, COSV59708272; ClinVar: likely benign; called by muse, mutect2
- GABPB2 | c.390C>T p.V130= | Silent (SNP) | VAF 94/322 reads (29%) | catalogued as rs751595714, COSV64461220; called by muse, mutect2, varscan2
- KCND1 | c.258C>T p.R86= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1569518736, COSV54414652; called by muse, mutect2, varscan2
- PCDHA13 | c.1554C>T p.Y518= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV56528392, COSV99166429; called by muse, mutect2, varscan2
- PNN | c.1545A>G p.Q515= | Silent (SNP) | VAF 74/233 reads (32%) | catalogued as COSV53767627; called by muse, mutect2, varscan2
- MIR514A2 | n.46T>A | RNA (SNP) | VAF 77/509 reads (15%) | called by muse, mutect2, varscan2
